Somatic mutation profile of tumor specimen TCGA-DU-6401-01A (aliquot TCGA-DU-6401-01A-11D-1705-08) from TCGA case TCGA-DU-6401, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 31.7 years (11,595 days).
Specimen TCGA-DU-6401-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae06acfc-a8d5-4aa3-8ba1-ec93d8689c0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6401-10A (Blood Derived Normal), aliquot TCGA-DU-6401-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9007a11c-7d68-42f9-bbef-ab2940e6413c

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Silent 4, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 28/81 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 19/28 reads (68%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BCLAF3 | c.853C>A p.R285S | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.272); catalogued as COSV61413708; called by muse, mutect2, varscan2
- C1orf174 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.482); catalogued as COSV64365777; called by muse, mutect2
- CELSR1 | c.3342C>G p.N1114K | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV53085916; called by muse, mutect2, varscan2
- DDX55 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV53015836; called by muse, mutect2
- DHDDS | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs753558346, COSV52576228; called by muse, mutect2, varscan2
- DYNC1H1 | c.12205A>G p.I4069V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.02); catalogued as COSV64136154; called by muse, mutect2, varscan2
- GLUD2 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 23/241 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60151749, COSV60152907; called by muse, mutect2
- HDAC6 | c.3424A>G p.N1142D | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57806606; called by muse, mutect2
- KCNT1 | c.1104G>T p.M368I (on ENST00000488444; = p.M387I on NM_020822.3) | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV53699827; called by muse, mutect2, varscan2
- LPAR4 | c.202A>G p.M68V | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV70912500; called by muse, mutect2, varscan2
- MAGEC1 | c.2465C>T p.S822L | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.063); catalogued as COSV53571416; called by muse, mutect2
- MAP2K3 | c.998C>T p.T333M (on ENST00000342679 / NM_145109.3; = p.T304M on NM_002756.4) | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.748); catalogued as rs35755743; called by muse, mutect2, varscan2
- SLCO1B1 | c.431T>C p.I144T | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV57009865; called by muse, mutect2, varscan2
- SLIT2 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV56568854; called by muse, mutect2, varscan2
- XPO6 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748385668, COSV58965570; called by muse, mutect2, varscan2
- ZFYVE26 | c.3512G>A p.S1171N | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV61327264; called by muse, mutect2, varscan2
- ATRX | c.1074dup p.L359Tfs*3 | Frame Shift Ins (INS) | VAF 48/128 reads (38%) | called by mutect2, varscan2
- ESCO2 | c.440_443del p.K147Ifs*23 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | called by mutect2, pindel, varscan2
- CEACAM5 | c.1809G>A p.S603= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as rs782143681, COSV55751793; called by muse, mutect2, varscan2
- ENPP2 | c.1374T>C p.P458= (on ENST00000075322 / NM_001040092.3; = p.P510= on NM_006209.5) | Silent (SNP) | VAF 68/131 reads (52%) | catalogued as COSV50013245; called by muse, mutect2, varscan2
- LAMA2 | c.582T>C p.D194= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV70344705; called by muse, mutect2, varscan2
- PTCD1 | c.822C>T p.I274= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as COSV52862776; called by muse, mutect2, varscan2
